Gene-level copy-number profile of specimen HCM-BROD-0098-C15-85A from HCMI case HCM-BROD-0098-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 77.3 years (28,226 days).
Specimen HCM-BROD-0098-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78c41daf-966e-4ca0-b0b7-0805d2854575.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0098-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/399fe401-d2e2-4f9b-b038-0f8a8f5e8b7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2,468; copy number 2: 24,580; copy number 3: 15,903; copy number 4: 9,545; copy number 5: 4,919; copy number 6: 697; copy number 7: 664; copy number 8: 40; copy number 9: 12; copy number 10: 14; copy number 11: 13; copy number 12: 9; copy number 14: 16; copy number 16: 11.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,027,077–8,040,953, 2 genes: FAM90A12P, OR7E96P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,395 genes in 69 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,784,320–13,825,079, 207 genes, copy number 5 (broad region; genes not listed).
- chr1:15,111,815–19,210,266, 131 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:143,419,625–143,760,669, 16 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr1:143,905,487–145,708,148, 49 genes, copy number 5–9 (within-gene range 4–9): AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1.
- chr1:148,939,739–149,259,987, 8 genes, copy number 5 (within-gene range 4–5): RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3.
- chr2:84,821,650–85,905,199, 50 genes, copy number 5–6: TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1.
- chr2:181,887,851–197,786,762, 181 genes, copy number 5–6 (broad region; genes not listed).
- chr3:180,161,886–182,142,137, 39 genes, copy number 5: RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1.
- chr3:185,476,496–185,825,042, 6 genes, copy number 6 (within-gene range 4–6): TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1.
- chr3:189,631,389–198,123,232, 205 genes, copy number 5 (broad region; genes not listed).
- chr5:21,750,673–24,353,443, 22 genes, copy number 5–6 (within-gene range 4–6): CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:42,729,138–55,022,671, 118 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:25,983,812–34,535,229, 584 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:35,497,874–38,640,148, 76 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:57,770,619–57,837,046, 13 genes, copy number 5: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr8:7,200,756–7,290,402, 8 genes, copy number 6–8: AF228730.1, AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P.
- chr8:7,428,888–8,024,652, 43 genes, copy number 5: DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P.
- chr8:12,064,389–12,177,550, 9 genes, copy number 12 (within-gene range 3–12): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D.
- chr8:76,904,591–80,080,775, 29 genes, copy number 5 (within-gene range 4–5): AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2.
- chr8:81,149,107–94,104,322, 181 genes, copy number 5 (broad region; genes not listed).
- chr8:98,943,595–143,840,973, 630 genes, copy number 5–6 (broad region; genes not listed).
- chr9:61,190,003–61,666,386, 12 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr10:120,851,305–122,699,846, 30 genes, copy number 5 (within-gene range 3–5): WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, C10orf120.
- chr10:122,832,158–123,171,875, 13 genes, copy number 5: CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB, HMX3, HMX2, BUB3, RPS26P39.
- chr11:68,870,664–72,290,688, 116 genes, copy number 6–16 (broad region; genes not listed).
- chr11:77,878,720–79,441,030, 25 genes, copy number 5–11 (within-gene range 4–11): INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1.
- chr11:83,455,012–85,811,159, 20 genes, copy number 5: DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2.
- chr11:87,718,354–88,176,593, 15 genes, copy number 5: LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3, AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166.
- chr11:89,177,875–91,383,289, 72 genes, copy number 5 (broad region; genes not listed).
- chr12:53,708,517–81,998,962, 632 genes, copy number 5 (broad region; genes not listed).
- chr13:34,910,545–35,673,022, 7 genes, copy number 5: Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1.
- chr13:37,481,467–37,874,444, 6 genes, copy number 5: LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1.
- chr13:39,655,627–39,857,227, 6 genes, copy number 5: COG6, MIR4305, RNY4P14, CDKN2AIPNLP3, AZU1P1, SNORD116.
- chr13:73,054,976–73,227,260, 5 genes, copy number 5: KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr15:45,321,077–100,544,995, 1,314 genes, copy number 5–7 (broad region; genes not listed).
- chr15:101,116,603–101,979,093, 38 genes, copy number 7: AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:61,647,242–90,222,851, 770 genes, copy number 5–6 (broad region; genes not listed).
- chr19:13,731,760–27,984,984, 552 genes, copy number 5–6 (broad region; genes not listed).
- chr19:28,435,388–31,787,255, 56 genes, copy number 5: AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.
- chr22:15,282,557–16,390,887, 35 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6, ABCD1P4.

Autosomal genes at a single copy (total copy number 1): 807. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
